Surgical pathology report (de-identified scan), TCGA case TCGA-CC-5263, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site ILSBio, specimen TCGA-CC-5263-01A (Primary Tumor).

[page 1 of 3]
1CD-0-3

Carcinoma, hepatocellular, NOS 8170/3

Site: Liver C22-0

1/28/11 *for*

ID#:

Pathology Form

Specimen Information

Collected by: _____ Date: _____ Time: _____

Preserved by: _____ Date: _____ Time: _____

SPECIMEN TYPE (# of samples provided)							
Frozen		Paraffin Block		Blood/Serum/Plasma		Slide	
Diseased	Normal	Diseased	Normal	Diseased	Normal	Diseased	Normal
4	2	4	2			4	2
Time to LN2		Time to Formalin		Time to LN2			
11 min		12 min					

PATHOLOGICAL DESCRIPTION			
Primary Tumor			
Organ	Size	Extension of Tumor	Distance to NAT
Liver Tumor	1.5 x 1.4 x 1 cm		5 cm
Lymph Nodes			
Location	# Examined	# Metastasized	
Distant Metastasis			
Organ	Detailed Location	Size	
Pathological Staging			
pT ₃ N ₀ M ₀		Stage: III	
Notes:			
UUID: 3136CA38-995E-486B-97F2-D37AF68EFA4C TCGA-CC-5263-01A-PR Redacted 			

Relay (initials)	Date Reviewed:	9/30/10

[page 2 of 3]
ID#:

Microscopic Description

Histological Pattern											
Cell Distribution			+	-	Structural Pattern			+	-		
Diffuse			☒		Streaming						
Mosaic					Storiform						
Necrosis			☒		Fibrosis						
Lymphocytic Infiltration					Palisading						
Vascular Invasion					Cystic Degeneration						
Clusterized					Bleeding						
Alveolar Formation					Myxoid Change						
Indian File					Psammoma/Calcification						
Cellular Differentiation											
Squamous	+	-	Adenomatous	+	-	Sarcomatous	+	-	Lymphomatous	+	-
Squamoid Cell			Glandular cell	☒		Round Cell			Large Cell		
Spindle Cell			Cell Stratification			Fibroblast			Small Cell		
Keratin			Secretion			Osteoblast			RS Cell/RS Like		
Desmosome			Intracyt. Vacuole			Lipoblast			Inflam. Cell		
Pearl			Gland formation			Myoblast			Plasma Cell		
Cellular Differentiation: Well Moderate ☒ Poor											
Nuclear Appearance											
Nuclear Atypia:						0	I	II	III		
Aniso Nucleosis							☒				
Hyperchromatism								☒			
Nucleolar Prominent								☒			
Multinucleated Giant Cell								☒			
Mitotic Activity								☒			
Nuclear Grade:											

IHC Data			
Marker	Result	Value	Date
ER	☐ Negative ☐ Positive		
PR	☐ Negative ☐ Positive		
Her-2/neu	☐ Negative ☐ Positive		
B-Cell Marker	☐ Negative ☐ Positive		
T-Cell Marker	☐ Negative ☐ Positive		
Other:	☐ Negative ☐ Positive		
Other:	☐ Negative ☐ Positive		

Final Pathology Report

Histological Diagnosis: Hepatocarcinoma
(moderately differentiated)
T3N1M1 IV-stage IIIA Grade: II

Comments:

Principal Investigator

Pathologist

Date

[page 3 of 3]
CONSOLIDATED DIAGNOSTIC PATHOLOGY FORM*

Microscopic Appearance:

1. Histological pattern:

CELL DISTRIBUTION			STRUCTURAL PATTERN		
	+	-		+	-
Diffuse			Streaming		
Mosaic	X	X	Storiform		
Necrosis	X		Fibrosis		
Lymphocytic Infiltration	X		Palisading		
Vascular Invasion		X	Cystic Degeneration		
Clusterized	X		Bleeding		
Alveolar Formation		X	Myxoid Change		
Indian File		X	Psammoma/Calcification		

2. Cellular features:

Squamous			Adenomatous			Sarcomatous			Lymphomatous		
	+	-		+	-		+	-		+	-
Squamous Cell			Glandular cell	X		Round Cell			Large Cell		
Spindle Cell			Cell Stratification	X		Fibroblast			Small Cell		
Keratin			Secretion	X		Osteoblast			RS Cell/RS Like		
Desmosome			Intracyt. Vacuole	X		Lipoblast			Inflam. Cell		
Pearl			Gland formation	X		Myoblast			Plasma Cell		

Otherwise Specified:

D1 70% D2 48% D3 70% D4 25% because 10%

2. Cellular Differentiation:

Well	Moderately	Poor
X		

3. Nuclear Atypia:

Nuclear Appearance		0	I	II	III
Aniso Nucleosis			X		
Hyperchromatism			X		
Nucleolar Prominent			X		
Multinucleated Giant Cell			X		
Mitotic Activity			X		
Nuclear Grade			X		

Histological Diagnosis: *Hepatocellular Carcinoma, G1*

Comments: _____

Date _____

*(INTEGRATED REPORT OF FINDINGS BY CONTRIBUTOR AND

PATHOLOGIST STAFF FOR RESEARCH USE ONLY).

Source: NCI Genomic Data Commons file 1e6d0fe4-437d-4212-b286-3ed0f4b04826 (TCGA-CC-5263.3136CA38-995E-4B6B-97F2-D37AF68EFA4C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).